Somatic mutation profile of tumor specimen TARGET-10-PASXLT-09A (aliquot TARGET-10-PASXLT-09A-01D) from TARGET case TARGET-10-PASXLT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,491 days).
Specimen TARGET-10-PASXLT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89079161-6db4-42b9-b7c6-3ada292acb33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASXLT-10A (Blood Derived Normal), aliquot TARGET-10-PASXLT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddd0ea87-d82f-4f9d-83c1-4bb97ea4abff

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC183 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs751657121, COSV61037703; called by muse, mutect2, varscan2
- DSCAML1 | c.2761G>A p.D921N (on ENST00000321322; = p.D861N on NM_020693.4) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV58396291; called by muse, mutect2, varscan2
- NOTCH1 | c.4778T>C p.L1593P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024711; called by muse, varscan2
- PHF6 | c.737C>A p.S246Y (on ENST00000332070 / NM_032458.3; = p.S247Y on NM_032335.3) | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59701399; called by muse, mutect2, varscan2
- PRKD2 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99353986; called by muse, mutect2
- QPCTL | c.900_901insGGGTCTGCAC p.R301Gfs*81 | Frame Shift Ins (INS) | VAF 33/101 reads (33%) | called by mutect2, varscan2
- RAD21 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- DHX32 | c.240C>T p.I80= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs1564832238, COSV52938694; called by muse, mutect2, varscan2
- PNMA8B | c.1434A>G p.K478= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as rs1192624328; called by muse, mutect2, varscan2
